Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4824, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4824-01A (Primary Tumor).

FINAL DIAGNOSIS

Part 1: KIDNEY, LEFT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, 3.5 cm, CONVENTIONAL (CLEAR) CELL TYPE. FUHRMAN'S NUCLEAR GRADE IS III OF IV.
- B. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- C. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- D. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- E. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- F. THE NON-NEOPLASTIC KIDNEY WITH SIMPLE CYSTS.
- G. TNM STAGE I: pT1a NX MX.
- H. TNM HISTOLOGIC GRADE = G3.

TCGA-B0-4824

Source: NCI Genomic Data Commons file 76b55153-8636-498b-a040-0acd7807cb7a (TCGA-B0-4824.C2BFE026-4EB1-4D17-9084-41A0B19297C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).